Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5469, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5469-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-5469

***** Addended Report *****
[REDACTED]
PATHOLOGIC DIAGNOSIS:

A/1) LEFT RADICAL NEPHRECTOMY:

RENAL CELL CARCINOMA, clear cell type (11.3 cm), Fuhrman Grade II/IV.
The tumor focally abuts but does not invade the renal capsule.
No lymphovascular invasion seen.
Renal vein is negative for tumor.

Ureter (including margin) is negative for tumor.

AJCC stage (6th edition): T2 N0 MX (see below)

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

B/2) HILAR MASS:

Lymph node (2.6 cm) with sinus histiocytosis and follicular hyperplasia, negative for tumor.
Fifteen (15) additional small hilar lymph nodes are negative for tumor.

CLINICAL DATA:

History: None given.
Operation: Left laparoscopic radical nephrectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Lt renal mass.

TISSUE SUBMITTED:

A/1) lt kidney - to Tissue Bank.
B/2) hilar mass.

GROSS DESCRIPTION:

The specimen is received fresh in two parts, each labeled with the patient's name and unit number.

Part A, "left kidney", consists of a 1371 gram left radical nephrectomy specimen (31.0 x 14.0 x 8.0 cm) including perirenal fat (measuring in thickness from 2.0 to 2.5 cm). The left adrenal gland is not present. Extending from the renal pelvis is the ureter (11.5 cm in length x 0.3 cm in diameter), left renal vein (1.5 cm in length x 3.0 cm in diameter), and left renal artery (1.8 cm in length x 0.6 cm in diameter). The majority of the renal parenchyma consists of a poorly-circumscribed, lobulated, focally hemorrhagic, tan/white to gray to orange soft, focally cystic mass (11.3 x 10.8 x 10.5 cm) that is 2.2 cm to the renal vein margin, 10.6 cm to the ureter margin, 2.4 cm to the renal artery margin, and grossly abuts the kidney capsule (inked black). The remainder of the renal cortex is tan/brown with a well-defined corticomedullary junction. The pelvis and calyces are covered by smooth glistening mucosa. The adipose tissue is thinly sectioned and no lymph nodes are found. Representative sections of tumor are taken for cytogenetics, tissue banking, and Dr. Sabrina Signoretti's lab. Representative sections of normal kidney are taken for electron microscopy, immunofluorescence, and tissue banking.

[page 2 of 3]
CGA-CZ-5469

[page 3 of 3]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT:

Cytogeneticist: [REDACTED]

KARYOTYPE:

T1: 46,XY,add(3)(p21)[1]/71-100<4n>,XXYY,-1,i(1)(q10),-3,-3,-6,-6,-9,-9,-14,-14,+mar1x2[cp2]

T2: 94-1104n> XXYY,add(3)(p21),+mar1x2-3[cp3]

METAPHASES COUNTED: 6

ANALYZED: 6

SCORED:

BANDING: GTG

INTERPRETATION:

Two samples from the same tumor were received.

Smiler aberrations were seen in both samples, including add(3)(p21), a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

Source: NCI Genomic Data Commons file aa45daaa-4682-4036-8c3e-ad6fdc17382e (TCGA-CZ-5469.6FC67C3C-DD9B-4257-840E-6DBA9E5831A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).